Somatic mutation profile of tumor specimen 0D98P0 from CCDI case PBBIFL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astroblastoma; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 12.7 years (4,646 days).
Specimen 0D98P0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8335051-a1b4-4b4f-ac42-2cc2aede1d42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D98P3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/305cb3a6-6c4d-4915-b6fd-8bac2e2e7fc9

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, Silent 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 46/427 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV55608355; called by muse, varscan2
- ARHGAP21 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 300/756 reads (40%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.627); catalogued as rs761547283, COSV100256647; called by muse, varscan2
- MROH1 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 80/771 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs769118455; called by muse, varscan2
- MTM1 | c.66G>A p.T22= | Splice Region (SNP) | VAF 90/860 reads (10%) | catalogued as rs781793926; called by muse, varscan2
- THOC3 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 57/540 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.075); called by muse, varscan2
- ZNF185 | c.1664C>G p.P555R | Missense Mutation (SNP) | VAF 320/826 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, varscan2
- ARFGEF3 | c.5682C>T p.N1894= | Silent (SNP) | VAF 74/352 reads (21%) | catalogued as rs765524399; called by muse, varscan2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 16/144 reads (11%) | called by muse, varscan2
- ZFYVE16 | c.3607+79C>T | Intron (SNP) | VAF 10/117 reads (9%) | called by muse, varscan2
